Somatic mutation profile of tumor specimen TCGA-FV-A23B-01A (aliquot TCGA-FV-A23B-01A-11D-A16V-10) from TCGA case TCGA-FV-A23B, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Age at diagnosis: 70.6 years (25,788 days).
Specimen TCGA-FV-A23B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d77c5877-cd29-4f51-8177-f98e9718c03e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FV-A23B-11A (Solid Tissue Normal), aliquot TCGA-FV-A23B-11A-11D-A16V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24b160c1-faed-45e0-9d68-5d554424ead1

The open-access MAF lists 100 somatic variants for this specimen: 69 protein-altering or splice-affecting, 27 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 27, Nonsense Mutation 4, In Frame Del 3, Frame Shift Ins 2, 3'UTR 2, Splice Region 1, 5'UTR 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA6 | c.3649A>T p.M1217L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52643135; called by muse, mutect2, varscan2
- ABCC8 | c.4054C>T p.R1352C | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1434876771, COSV56852264; called by muse, mutect2, varscan2
- ABHD17B | c.851A>C p.E284A | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV61008741; called by muse, mutect2, varscan2
- ACP7 | c.967A>G p.K323E | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.231); catalogued as COSV58700474; called by muse, mutect2
- ADARB2 | c.1217T>G p.V406G | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67233041; called by muse, mutect2, varscan2
- AKIRIN1 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.16); PolyPhen benign (0.254); catalogued as rs781305153, COSV65910299; called by muse, mutect2, varscan2
- ARHGAP35 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs779738931, COSV68334438; called by muse, mutect2, varscan2
- ARID1A | c.4624G>T p.E1542* | Nonsense Mutation (SNP) | VAF 28/41 reads (68%) | catalogued as COSV61371858, COSV61383029; called by muse, mutect2, varscan2
- BRCA1 | c.4411G>C p.G1471R | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.055); catalogued as COSV104398463, COSV58796577; called by muse, mutect2
- C15orf39 | c.415T>C p.C139R | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62297713; called by muse, mutect2, varscan2
- CDKL2 | c.128T>C p.M43T | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV56734874; called by muse, mutect2, varscan2
- CELSR3 | c.8543G>A p.R2848H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.178); catalogued as rs757360789; called by muse, varscan2
- CENPC | c.298G>T p.V100F | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV56625414; called by muse, mutect2, varscan2
- CLTCL1 | c.4868A>T p.E1623V (on ENST00000427926 / NM_007098.4; = p.E1566V on NM_001835.4) | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV53206541; called by muse, mutect2, varscan2
- CLVS2 | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 9/12 reads (75%) | catalogued as COSV51567693; called by muse, mutect2, varscan2
- COL12A1 | c.4616C>T p.T1539M | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373216375, COSV59389127; called by muse, mutect2, varscan2
- COL6A6 | c.384G>T p.K128N | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV62033693; called by muse, mutect2, varscan2
- CRLF1 | c.811A>T p.K271* | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | catalogued as COSV62260921; called by muse, mutect2, varscan2
- CTTN | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1471298429, COSV57234992; called by muse, mutect2, varscan2
- DGKE | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV52351027; called by muse, mutect2, varscan2
- EXOC1 | c.1120A>G p.T374A | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.042); catalogued as COSV62121518; called by muse, mutect2, varscan2
- FAM220A | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.846); catalogued as rs760742712, COSV57627261; called by muse, mutect2, varscan2
- FBXW11 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.102); catalogued as rs773518789, COSV51612643; called by muse, mutect2, varscan2
- FLRT2 | c.1655T>C p.I552T | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.041); catalogued as COSV58147913; called by muse, mutect2, varscan2
- GPAM | c.914G>T p.R305L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as COSV62082208; called by muse, mutect2, varscan2
- GPCPD1 | c.139G>A p.G47S | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.055); catalogued as COSV66831545; called by muse, mutect2, varscan2
- GRM8 | c.1103G>T p.G368V | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV58856664; called by muse, mutect2, varscan2
- GRM8 | c.1102G>T p.G368C | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV58856683; called by muse, mutect2, varscan2
- HTR1A | c.1127A>T p.H376L | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.096); catalogued as COSV60502351; called by muse, mutect2, varscan2
- HTR2C | c.1273G>T p.E425* | Nonsense Mutation (SNP) | VAF 68/179 reads (38%) | catalogued as rs781872799, COSV52221051, COSV52226263; called by muse, mutect2, varscan2
- IL18R1 | c.400A>C p.K134Q | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); catalogued as COSV52126504; called by muse, mutect2, varscan2
- IL31RA | c.1213G>C p.E405Q | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.618); catalogued as COSV51684111; called by muse, mutect2, varscan2
- ITGA1 | c.31G>C p.V11L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV50892996; called by muse, mutect2
- JAG2 | c.2987G>A p.R996H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1486931022, COSV59311924; called by muse, varscan2
- LRIF1 | c.1499A>G p.K500R | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as COSV63898198; called by muse, mutect2, varscan2
- LRP4 | c.3891G>A p.M1297I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV66137874, COSV66138119; called by muse, varscan2
- MATR3 | c.790T>C p.S264P | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.954); catalogued as COSV63079065; called by muse, mutect2, varscan2
- MTMR4 | c.2189G>A p.G730E | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV60202594; called by muse, mutect2, varscan2
- MTX3 | c.15G>T p.L5F | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV72512457; called by muse, mutect2, varscan2
- MUC16 | c.29560G>C p.V9854L | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs777355694, COSV67450415; called by muse, mutect2, varscan2
- MYOM2 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs536708249, COSV50719390; called by muse, mutect2, varscan2
- NUF2 | c.1334A>G p.Y445C | Missense Mutation (SNP) | VAF 58/248 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs755556279, COSV54845710; called by muse, mutect2, varscan2
- NUP210L | c.2438T>C p.F813S | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV55154748; called by muse, mutect2, varscan2
- OPLAH | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV70678957; called by muse, mutect2, varscan2
- OR13H1 | c.145A>G p.I49V | Missense Mutation (SNP) | VAF 83/228 reads (36%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as COSV58548247; called by muse, mutect2, varscan2
- OR8H1 | c.656C>A p.S219Y | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV57295404; called by muse, mutect2, varscan2
- PF4V1 | c.167G>A p.R56K | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.097); catalogued as COSV56953770; called by muse, mutect2, varscan2
- PIK3R4 | c.2348A>T p.E783V | Missense Mutation (SNP) | VAF 71/183 reads (39%) | SIFT tolerated (0.84); PolyPhen benign (0.006); catalogued as COSV63243180; called by muse, mutect2, varscan2
- PRMT6 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.052); catalogued as rs539124873, COSV63656223; called by muse, mutect2, varscan2
- RPS6KA3 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65389004; called by muse, mutect2, varscan2
- SCN2B | c.532A>G p.M178V | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54051651; called by muse, mutect2, varscan2
- STXBP5L | c.868A>G p.I290V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs371884493; called by muse, mutect2, varscan2
- SYT16 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs758851790, COSV70858745; called by muse, mutect2, varscan2
- TASOR2 | c.6410A>T p.D2137V | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV60169012; called by muse, mutect2, varscan2
- TSPAN7 | c.217G>C p.G73R | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54533374; called by muse, mutect2, varscan2
- XKR5 | c.596T>A p.L199Q | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68398716; called by muse, mutect2, varscan2
- XYLT2 | c.142A>G p.R48G | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.767); catalogued as rs1369599573; called by muse, mutect2
- ZDHHC13 | c.575A>G p.K192R | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.215); catalogued as rs770397481, COSV67981766; called by muse, mutect2, varscan2
- ZNF804A | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.78); PolyPhen benign (0.014); catalogued as COSV56464811; called by muse, mutect2, varscan2
- ADCY10 | c.3551_3553del p.F1184_H1185delinsY | In Frame Del (DEL) | VAF 27/111 reads (24%) | called by mutect2, pindel, varscan2
- ALDH6A1 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4465dup p.E1489Gfs*3 | Frame Shift Ins (INS) | VAF 135/445 reads (30%) | called by mutect2, pindel, varscan2
- CARM1P1 | n.120C>A | Splice Region (SNP) | VAF 20/75 reads (27%) | called by muse, mutect2, varscan2
- CYP4F3 | c.426_437del p.E142_R146delinsD | In Frame Del (DEL) | VAF 14/46 reads (30%) | called by mutect2, pindel, varscan2
- HLA-B | c.402_403insT p.R135Sfs*4 | Frame Shift Ins (INS) | VAF 12/35 reads (34%) | called by mutect2, pindel
- IGHV1-2 | c.158T>C p.M53T | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- LMNA | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- MYH4 | c.4000del p.A1334Pfs*64 | Frame Shift Del (DEL) | VAF 13/26 reads (50%) | called by mutect2, pindel, varscan2
- ZNF134 | c.908_913del p.L303_V304del | In Frame Del (DEL) | VAF 9/42 reads (21%) | called by mutect2, pindel, varscan2
- CDH23 | c.3918G>A p.E1306= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV56482203; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3922C>T p.L1308= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as rs765512094, COSV62577082; called by muse, mutect2, varscan2
- CEP43 | c.867A>G p.L289= | Silent (SNP) | VAF 22/30 reads (73%) | catalogued as COSV62761453; called by muse, mutect2, varscan2
- CHST10 | c.225C>T p.L75= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as rs766638550, COSV51807086; called by muse, mutect2, varscan2
- DLL1 | c.1611G>A p.E537= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV64538295; called by muse, mutect2, varscan2
- ELAVL3 | c.177C>T p.F59= | Silent (SNP) | VAF 47/83 reads (57%) | catalogued as rs201270169; called by muse, mutect2, varscan2
- EVPL | c.1209C>A p.A403= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV56914566; called by muse, mutect2, varscan2
- HK3 | c.522G>A p.T174= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs762862821, COSV52843340; called by muse, mutect2, varscan2
- KIAA1755 | c.18C>T p.L6= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs757306792, COSV54079387; called by muse, mutect2, varscan2
- LMNA | c.1335G>T p.V445= | Silent (SNP) | VAF 29/57 reads (51%) | called by muse, mutect2, varscan2
- MYH1 | c.3489C>A p.A1163= | Silent (SNP) | VAF 24/38 reads (63%) | catalogued as COSV56854783; called by muse, mutect2, varscan2
- NDST3 | c.894A>G p.T298= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs372361471; called by muse, mutect2
- PC | c.2236C>T p.L746= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as rs757893864, COSV58993713; called by muse, mutect2, varscan2
- PLCL1 | c.2511G>A p.E837= | Silent (SNP) | VAF 44/103 reads (43%) | catalogued as rs1045149769, COSV101407183, COSV70863180, COSV70871729; called by muse, mutect2, varscan2
- POTEH | c.573A>G p.R191= | Silent (SNP) | VAF 52/374 reads (14%) | catalogued as COSV100624910; called by muse, mutect2, varscan2
- PPM1H | c.1215C>T p.Y405= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV57377883; called by muse, mutect2, varscan2
- PRPF38B | c.1491T>C p.S497= | Silent (SNP) | VAF 72/190 reads (38%) | catalogued as rs778732950, COSV64224353; called by muse, mutect2, varscan2
- PSMD11 | c.987C>T p.N329= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV55580511; called by muse, mutect2, varscan2
- ROS1 | c.694C>T p.L232= | Silent (SNP) | VAF 35/46 reads (76%) | catalogued as COSV100877659, COSV63859947; called by muse, mutect2, varscan2
- SCNN1B | c.630T>C p.S210= | Silent (SNP) | VAF 30/36 reads (83%) | catalogued as COSV56308702; called by muse, mutect2
- SLC30A1 | c.435C>G p.G145= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV65361448, COSV65361643; called by muse, mutect2, varscan2
- STAB2 | c.4788C>T p.R1596= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as rs751986200, COSV66339454; called by muse, mutect2, varscan2
- TRPC4 | c.1329C>T p.S443= | Silent (SNP) | VAF 37/98 reads (38%) | catalogued as COSV59011972; called by muse, mutect2, varscan2
- WDFY3 | c.6108A>G p.G2036= | Silent (SNP) | VAF 34/84 reads (40%) | catalogued as COSV55710760; called by muse, mutect2, varscan2
- ZNF185 | c.1065G>A p.T355= | Silent (SNP) | VAF 34/78 reads (44%) | catalogued as rs1041593473, COSV59276619, COSV59277695; called by muse, mutect2, varscan2
- ZNF256 | c.678T>C p.R226= | Silent (SNP) | VAF 35/117 reads (30%) | catalogued as rs962502572, COSV56599187; called by muse, mutect2
- ZNF419 | c.360C>T p.L120= | Silent (SNP) | VAF 39/112 reads (35%) | catalogued as rs1167245214, COSV55658336, COSV55662234; called by muse, mutect2, varscan2
- C2CD4A | c.*592G>A | 3'UTR (SNP) | VAF 13/33 reads (39%) | catalogued as COSV100831062; called by muse, mutect2, varscan2
- CAND1 | c.-9G>A | 5'UTR (SNP) | VAF 12/20 reads (60%) | catalogued as COSV101604398; called by muse, varscan2
- IDS | c.418+106G>A | Intron (SNP) | VAF 38/103 reads (37%) | catalogued as COSV100557949; called by muse, mutect2, varscan2
- OLIG1 | c.*658G>A | 3'UTR (SNP) | VAF 14/23 reads (61%) | catalogued as COSV100287164; called by muse, mutect2, varscan2
